Gene-level copy-number profile of tumor specimen TCGA-EE-A2MN-06A from TCGA case TCGA-EE-A2MN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.9 years (21,885 days).
Specimen TCGA-EE-A2MN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a1b60205-a659-491d-bebb-f3c9c2b0a2e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2MN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/61900816-41cf-4f25-8ff8-7ff1622dfabf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,413; copy number 2: 38,750; copy number 3: 5,301; copy number 4: 3,046; copy number 5: 1,172; copy number 7: 122; copy number 11: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2MN-06A-11D-A191-01): tumor purity 0.79, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,309 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:187,706,561–197,935,478, 96 genes, copy number 5 (broad region; genes not listed).
- chr1:237,042,184–248,919,946, 274 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:70,972–10,239,863, 217 genes, copy number 5 (broad region; genes not listed).
- chr7:16,461,481–32,894,131, 310 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:20,836,447–22,706,703, 68 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr22:31,388,733–33,922,841, 69 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr22:36,388,626–43,015,149, 275 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,992. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
